Gene-level copy-number profile of tumor specimen TCGA-93-A4JP-01A from TCGA case TCGA-93-A4JP, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.7 years (23,620 days).
Specimen TCGA-93-A4JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.38c64410-8d90-49bd-a74e-af15b7b6737c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-93-A4JP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2be5e28d-d118-4f20-b221-6e6a70d004ae

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,336; copy number 3: 25; copy number 4: 45,396; copy number 5: 11,991; copy number 9: 26; copy number 10: 10; copy number 11: 29; copy number 12: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-93-A4JP-01A-11D-A24O-01): tumor purity 0.27, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 46 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:3,284,120–3,478,978, 8 genes, copy number 10: AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,580,754, 2 genes, copy number 10: RN7SL39P, AP002472.1.
- chr18:11,326,270–11,552,847, 7 genes, copy number 12: AP005139.1, AP005229.1, AP005229.2, AP001109.1, LINC01928, LINC01255, AP001017.1.
- chr18:12,911,186–13,827,323, 29 genes, copy number 11: STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
